Gene-level copy-number profile of tumor specimen HTMCP-02-06-01163-01A from CGCI case HTMCP-02-06-01163, project CGCI-HTMCP-LC (HIV+ Tumor Molecular Characterization Project - Lung Cancer). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung.
Specimen HTMCP-02-06-01163-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 8a290bc0-373f-4227-92a5-2439a044409d.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HTMCP-02-06-01163-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,233 have no estimate.
https://portal.gdc.cancer.gov/files/efec51bd-2af4-4f8b-a147-679e185d6d60

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 511; copy number 2: 8,995; copy number 3: 9,817; copy number 4: 26,263; copy number 5: 3,498; copy number 6: 5,876; copy number 7: 1,657; copy number 8: 386; copy number 9: 1,123; copy number 10: 62; copy number 11: 2; copy number 13: 73; copy number 14: 22; copy number 16: 35; copy number 22: 10; copy number 24: 55; copy number 26: 1; copy number 30: 4.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,387 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:484,107–56,955,864, 965 genes, copy number 9–13 (within-gene range 9–26) (broad region; genes not listed).
- chr7:57,060,590–62,275,678, 55 genes, copy number 9: PHKG1P4, AC122133.1, ZNF479, AC099654.11, AC099654.2, MTATP6P8, MTCO3P10, MTND4LP32, MTND4P4, MTND5P6, MTCYBP29, GUSBP10, MTND1P4, MTND2P6, MTCO1P10, MTCO2P10, MTCO3P4, AC099654.7, MTND4P5, MTND5P7, MTCYBP5, GUSBP12, AC099654.1, RNU7-157P, AC099654.3, AC237221.2, AC237221.1, MIR3147, VN1R28P, SAPCD2P2, ZNF716, AC092175.1, NCOR1P3, AC064862.6, AC064862.7, BSNDP4, AC064862.1, AC064862.5, AC064862.2, AC064862.4, AC064862.3, AC023141.4, AC023141.8, AC023141.5, AC023141.12, AC023141.2, AC023141.9, AC023141.11, AC023141.3, AC023141.1, AC023141.10, AC023141.6, AC023141.7, AC023141.13, AC128676.1.
- chr7:63,556,598–64,736,743, 64 genes, copy number 9–13 (broad region; genes not listed).
- chr7:142,520,090–142,793,368, 41 genes, copy number 10: TRBV5-7, TRBV7-9, TRBV13, TRBV10-3, TRBV11-3, TRBV12-3, TRBV12-4, TRBV12-5, TRBV14, TRBV15, TRBV16, TRBV17, TRBV18, TRBV19, TRBV20-1, TRBV21-1, TRBV22-1, TRBV23-1, TRBV24-1, MTRNR2L6, TRBV25-1, TRBVA, TRBV26, TRBVB, TRBV27, TRBV28, PGBD4P1, AC244472.1, TRBV29-1, PRSS1, PRSS2, PRSS3P1, WBP1LP1, TRBD1, TRBJ1-1, TRBJ1-2, TRBJ1-3, TRBJ1-4, TRBJ1-5, TRBJ1-6, TRBC1.
- chr7:142,801,041–142,802,748, 1 gene, copy number 10: TRBC2.
- chr14:21,723,713–22,501,663, 91 genes, copy number 9–24 (broad region; genes not listed).
- chr14:22,547,506–22,552,156, 1 gene, copy number 24: TRAC.
- chr16:34,266,041–35,912,516, 81 genes, copy number 9–16 (broad region; genes not listed).
- chr16:70,114,332–70,173,483, 2 genes, copy number 11 (within-gene range 8–11): PDPR, AC009060.1.
- chr16:74,367,462–75,286,800, 28 genes, copy number 9–10 (within-gene range 8–10): AC009053.2, NPIPB15, AC009053.4, CLEC18B, AC009053.3, GLG1, RNU6-237P, Y_RNA, AC009153.1, HSPE1P7, RFWD3, TMPOP2, MLKL, FA2H, AC009132.1, WDR59, ZNRF1, AC099508.1, LDHD, AC099508.2, ZFP1, AC009078.1, CTRB2, CTRB1, AC009078.2, BCAR1, AC009078.3, RNU6-758P.
- chr19:39,406,847–40,348,527, 54 genes, copy number 10–30 (within-gene range 2–30): ZFP36, MIR4530, PLEKHG2, RPS16, SUPT5H, TIMM50, DLL3, SELENOV, EID2B, AC011500.3, TDGF1P7, EID2, AC011500.2, AC011500.1, RPS29P24, RPS29P25, RPS29P26, LGALS13, AC005176.2, AC005176.1, RPS29P30, LGALS16, LGALS17A, AC005515.1, AC093063.1, RPS29P27, LGALS14, AC006133.1, CLC, LEUTX, AC005393.1, DYRK1B, MIR6719, FBL, FCGBP, PRR13P5, PSMC4, ZNF546, AC007842.1, ZNF780B, AC005614.2, ZNF780A, AC005614.1, VN1R96P, MAP3K10, TTC9B, CCNP, AKT2, AC118344.1, MIR641, RNU6-945P, C19orf47, Y_RNA, Y_RNA.
- chr19:56,316,524–56,338,648, 4 genes, copy number 13 (within-gene range 4–13): Y_RNA, VN2R17P, AC006116.1, AC006116.3.

Autosomal genes at a single copy (total copy number 1): 511. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
